Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A907, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A907-01A (Primary Tumor).

[page 1 of 2]
Results

SURG PATH FINAL REPORT

Service Location

Name

Address

Phone

Patient Information

Patient Name

Sex

DOB

Phone

Patient Release Status:

This result is not viewable by the patient.

Collection Information

Resulting Agency

Entry Date

Component Results

Component

Value

SURG PATH FINAL
REPORT

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
C539

9/11/21/14

Accession #: [REDACTED]

Specimen:

Date of Procedure:

Performing Clinician: [REDACTED]

- A. Anterior cervix
- B. Posterior cervix

Diagnosis:

A. Anterior cervix, biopsy:

- Superficial fragments of squamous cell carcinoma (see comment).

COMMENT: The specimen is tangentially sectioned, with insufficient stroma to evaluate for invasion.

B. Posterior cervix, biopsy:

- Invasive squamous cell carcinoma, moderate to poorly differentiated (see comment).

COMMENT: The tissue is tangentially sectioned precluding accurate evaluation of the depth of invasion. The carcinoma is at least superficially invasive. Clinical correlation is

Printed by [REDACTED]

[page 2 of 2]
recommended.

[REDACTED] MD
(Electronically signed by)
Verified: [REDACTED]

Gross:

A. The specimen is labeled "ant". Received in formalin is a 0.6 x 0.6 x 0.2 cm fragmented portion of tan-gray tissue. The specimen is submitted in toto in cassette A.

B. The specimen is labeled "posterior lip of cervix". Received in formalin is a 0.5 x 0.5 x 0.2 cm aggregate of firm tan tissue and clotted blood. The specimen is submitted in toto in cassette B.

Accession #: [REDACTED]

Microscopic:

A histologic examination has been performed.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Result History

SURG PATH FINAL REPORT

(Order [REDACTED] or [REDACTED] Order Result History Report.)

Lab Information

Resulting Agency
[REDACTED]

Lab Collection Information

Collection Date and Time
[REDACTED]

IDs

Order #
[REDACTED]

Specimen #
[REDACTED]

[REDACTED] Printed by [REDACTED]

Source: NCI Genomic Data Commons file 613a38b9-3ffd-4994-929f-1cd36494d727 (TCGA-C5-A907.6AC8C0C6-A43A-427E-90D3-6584FC2F723E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).